Somatic mutation profile of tumor specimen MMRF_1328_1_BM_CD138pos (aliquot MMRF_1328_1_BM_CD138pos_T2_KAS5U_L00340) from MMRF case MMRF_1328, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.3 years (16,918 days).
Specimen MMRF_1328_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6489e422-b40d-4c44-aeee-207bea39b068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1328_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1328_1_PB_CD3pos_C4_KAS5U_L00341; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e570cacd-e176-4d1f-93c6-acad8369c769

The open-access MAF lists 830 somatic variants for this specimen: 257 protein-altering or splice-affecting, 120 silent, 453 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, 3'UTR 180, Intron 124, Silent 120, 5'UTR 83, 5'Flank 30, Nonsense Mutation 21, RNA 19, 3'Flank 17, Splice Region 7, Splice Site 2, In Frame Del 1.

Variants (750 of 830; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.4114G>A p.D1372N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs774406517, COSV64985927; called by muse, mutect2
- ABCC8 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV56856224; called by muse, mutect2, varscan2
- ALMS1 | c.9682del p.E3228Kfs*3 | Frame Shift Del (DEL) | VAF 77/181 reads (43%) | catalogued as COSV52505273; called by mutect2, pindel, varscan2
- AP5B1 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as rs769149476; called by muse, mutect2, varscan2
- APCDD1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs539268005; called by muse, mutect2, varscan2
- ARID2 | c.4831C>T p.Q1611* | Nonsense Mutation (SNP) | VAF 50/105 reads (48%) | catalogued as COSV57604009, COSV57609202; called by muse, mutect2, varscan2
- BAZ2A | c.5372C>T p.S1791F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1341084182; called by muse, mutect2, varscan2
- BORCS6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1049980190; called by muse, mutect2, varscan2
- C20orf85 | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.298); catalogued as COSV64519853; called by muse, mutect2, varscan2
- C9orf40 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV65228710; called by muse, mutect2, varscan2
- CACNB4 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52393725; called by muse, mutect2, varscan2
- CCDC116 | c.1835G>C p.G612A | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as rs368909911, COSV99489305; called by muse, mutect2, varscan2
- CCDC173 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1162825555; called by muse, mutect2, varscan2
- CCNE2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV100353810; called by muse, mutect2, varscan2
- CCNO | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs771896675; called by muse, mutect2, varscan2
- CDK13 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51699338; called by muse, mutect2, varscan2
- CELSR1 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53093425; called by muse, mutect2, varscan2
- CELSR3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770585899, COSV50841296, COSV50842619; called by muse, mutect2, varscan2
- CFAP57 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 53/103 reads (51%) | catalogued as COSV52540175; called by muse, mutect2, varscan2
- CSTF2T | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV58656260; called by muse, mutect2, varscan2
- CTNND2 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs200971466, COSV58915145; called by muse, mutect2, varscan2
- CTU2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1217267671; called by muse, mutect2, varscan2
- DMXL1 | c.5716C>T p.P1906S | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0.127); catalogued as COSV100224247; called by muse, mutect2, varscan2
- DNAAF2 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1226322286, COSV100023694; called by muse, mutect2, varscan2
- DOK1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51207860; called by muse, mutect2, varscan2
- DTNA | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV99311924; called by muse, mutect2, varscan2
- ELP5 | c.-77-8C>T | Splice Region (SNP) | VAF 27/53 reads (51%) | catalogued as rs1226139675, COSV100020961; called by muse, mutect2, varscan2
- ENKD1 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs1335599151; called by muse, mutect2, varscan2
- ERBB4 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs1315524347; called by muse, mutect2, varscan2
- ERI2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200942956; called by muse, mutect2, varscan2
- ETV2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1435567426, COSV55837536, COSV55838312; called by muse, mutect2, varscan2
- FAM135A | c.2219C>G p.S740C (on ENST00000370479 / NM_001351599.1; = p.S527C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV52049358; called by muse, mutect2, varscan2
- FAM135A | c.3076C>G p.P1026A (on ENST00000370479 / NM_001351599.1; = p.P813A on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1411222332, COSV52057693; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FAM8A1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1366000323, COSV52580283, COSV52580559; called by muse, mutect2, varscan2
- FBN2 | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs370804151, COSV52543595; called by muse, mutect2, varscan2
- FCGR2B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52683481; called by muse, mutect2, varscan2
- FREM3 | c.4213G>C p.D1405H | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61683066; called by muse, mutect2, varscan2
- FUT4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs373252364; called by muse, mutect2, varscan2
- FZD7 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99637545; called by muse, mutect2, varscan2
- GAB4 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs1339548779; called by muse, mutect2, varscan2
- GALNT4 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as rs1270498407; called by muse, mutect2, varscan2
- GP1BA | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.37); catalogued as rs762420701; called by muse, mutect2, varscan2
- GREB1 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV52197124; called by muse, mutect2, varscan2
- H2BC14 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1474071318, COSV60797493, COSV60797855; called by muse, mutect2, varscan2
- HLA-E | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV64927732; called by muse, mutect2, varscan2
- HMGN1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1234463105, COSV55742480; called by muse, mutect2, varscan2
- IGHV1-69 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1064564; called by muse, mutect2, varscan2
- JUNB | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV56879123; called by muse, mutect2, varscan2
- KCTD4 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 104/106 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368124187; called by muse, mutect2, varscan2
- KIAA0232 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.095); catalogued as COSV99072805; called by muse, mutect2, varscan2
- LIMD1 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs755423145; called by muse, mutect2, varscan2
- LOX | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV50241067; called by muse, mutect2, varscan2
- LRRK1 | c.5537C>T p.S1846L | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs201730508; called by muse, mutect2, varscan2
- MAMDC2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1434837171, COSV101015468; called by muse, mutect2, varscan2
- MELK | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53197611; called by muse, mutect2, varscan2
- METTL8 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1229764801; called by muse, mutect2, varscan2
- MFAP1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV51038958; called by muse, mutect2, varscan2
- MIER1 | c.1393G>A p.E465K (on ENST00000355356 / NM_001077701.3; = p.E482K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.167); catalogued as COSV62530283; called by muse, mutect2, varscan2
- MORC1 | c.1874T>A p.I625K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs755019604, COSV51727272; called by muse, mutect2, varscan2
- MPP7 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs761501342; called by muse, mutect2, varscan2
- MUC17 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs776869969; called by muse, mutect2, varscan2
- NABP1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1299419941, COSV100323028; called by muse, mutect2, varscan2
- NDST2 | c.1845G>A p.G615= | Splice Region (SNP) | VAF 31/59 reads (53%) | catalogued as COSV100013831; called by muse, mutect2, varscan2
- NLN | c.1734G>C p.Q578H | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101114093; called by muse, mutect2, varscan2
- NT5DC3 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as rs1282786233; called by muse, mutect2, varscan2
- OTUD1 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as rs1182699055; called by muse, mutect2, varscan2
- PHACTR4 | c.1240C>G p.P414A (on ENST00000373839 / NM_001350159.2; = p.P424A on NM_023923.4) | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as COSV65783087; called by muse, mutect2, varscan2
- PLCG2 | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as rs1458178159, COSV63868141; called by muse, mutect2, varscan2
- PLCH1 | c.1668+1G>A p.X556_splice (on ENST00000340059 / NM_001130960.2; = p.X568_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as rs761849818; called by muse, mutect2, varscan2
- POLR2A | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.012); catalogued as rs754205577, COSV59495557; called by muse, mutect2, varscan2
- PTCH1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.511); catalogued as COSV59461287; called by muse, mutect2, varscan2
- PTCHD3 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV101438933; called by muse, mutect2, varscan2
- PTGDR2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1430445362; called by muse, mutect2, varscan2
- PUSL1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60089494; called by muse, mutect2, varscan2
- QRICH1 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs1168988601, COSV100676749; called by muse, mutect2, varscan2
- RAD51AP2 | c.3089C>T p.S1030L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745674315, COSV67588028; called by muse, mutect2, varscan2
- RALGAPA1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV99355574; called by muse, mutect2, varscan2
- RAPGEF3 | c.1882G>A p.E628K (on ENST00000389212; = p.E586K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV99406147; called by muse, mutect2, varscan2
- RELN | c.5472G>C p.E1824D | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as COSV59007528; called by muse, mutect2, varscan2
- RIC1 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs755429039; called by muse, mutect2, varscan2
- RPS24 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs558584969; called by muse, mutect2, varscan2
- RTL5 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65454037; called by muse, mutect2, varscan2
- S1PR4 | c.1103G>A p.S368N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV55739889; called by muse, mutect2, varscan2
- SAFB | c.1816G>C p.D606H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs753468272; called by muse, mutect2, varscan2
- SCARF2 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV56733616; called by muse, mutect2, varscan2
- SCN1A | c.3418G>C p.E1140Q (on ENST00000303395 / NM_001202435.3; = p.E1129Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.968); catalogued as COSV57670936; called by muse, mutect2, varscan2
- SCN3A | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.988); catalogued as rs771117930, COSV51807783; ClinVar: uncertain significance; called by muse, varscan2
- SCN9A | c.1798A>C p.S600R | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV57612601; called by mutect2, varscan2
- SHARPIN | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs915756356; called by muse, mutect2
- SHH | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV99793200, COSV99793344; called by muse, mutect2, varscan2
- SLC12A6 | c.2810G>A p.R937Q (on ENST00000354181 / NM_001365088.1; = p.R886Q on NM_005135.2) | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs751727012, COSV51624720; called by muse, mutect2, varscan2
- SLC35E4 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.378); catalogued as COSV55898948; called by muse, mutect2, varscan2
- SLC39A7 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV63399708; called by muse, mutect2, varscan2
- SLC44A1 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58264531; called by muse, mutect2, varscan2
- SLC5A2 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs201951258; called by muse, mutect2, varscan2
- SMARCB1 | c.412G>A p.E138K (on ENST00000263121; = p.E184K on NM_003073.5) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs776374083, COSV54097296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX19 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56284842; called by muse, mutect2, varscan2
- SSC4D | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV51881134; called by muse, mutect2, varscan2
- STK11 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as rs758887235, COSV58826247; ClinVar: uncertain significance; called by muse, mutect2
- SULT1C2 | c.435G>C p.R145S | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52264837; called by muse, mutect2, varscan2
- TBC1D10C | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs771780848, COSV100408340; called by muse, mutect2, varscan2
- TFG | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1228814802, COSV53748710; called by muse, mutect2, varscan2
- THEG | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100700644, COSV61072756; called by muse, mutect2, varscan2
- THOC1 | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55273606; called by muse, mutect2, varscan2
- TIFAB | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs770431016; called by muse, mutect2, varscan2
- TJP1 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 66/129 reads (51%) | catalogued as COSV62042687; called by muse, mutect2, varscan2
- TMEM25 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150904224; called by muse, mutect2, varscan2
- TTC29 | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV57280495; called by muse, mutect2, varscan2
- USP53 | c.2869C>T p.H957Y | Missense Mutation (SNP) | VAF 97/189 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs762668639; called by muse, mutect2, varscan2
- VEGFC | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as rs1032468893; called by muse, mutect2, varscan2
- VGF | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.94); catalogued as rs35400704, COSV50801779, COSV99972772, COSV99973099; called by muse, mutect2, varscan2
- VMO1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750886340; called by muse, mutect2, varscan2
- WTAP | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 62/132 reads (47%) | catalogued as COSV100493395; called by muse, mutect2, varscan2
- XBP1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53275359; called by muse, mutect2, varscan2
- ZBTB7B | c.1439C>T p.S480F (on ENST00000292176; = p.S514F on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1260425718, COSV52692663; called by muse, mutect2, varscan2
- ZFHX3 | c.10215dup p.G3406Rfs*25 | Frame Shift Ins (INS) | VAF 47/100 reads (47%) | catalogued as rs762108866; called by mutect2, varscan2
- ZNF282 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768927441; called by muse, mutect2, varscan2
- ZNF77 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.225); catalogued as rs770910866, COSV58821557; called by muse, mutect2, varscan2
- ADGRL4 | c.1112_1138del p.A371_M380delinsV | In Frame Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, varscan2
- ADGRV1 | c.13322C>T p.S4441F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFDN | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- AHNAK2 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANGPT2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ANKRD63 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- API5 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATAD5 | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ATN1 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRWD1 | c.1306C>G p.Q436E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- C1orf146 | c.67-1G>C p.X23_splice | Splice Site (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- C20orf144 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CALCOCO1 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CCK | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CDKL2 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDKN1C | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CDSN | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CEP350 | c.9099C>A p.F3033L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CREB3L2 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CTNNA3 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DDX41 | c.798+5G>C | Splice Region (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- DVL2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EP300 | c.3768G>C p.Q1256H | Missense Mutation (SNP) | VAF 89/174 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPC2 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPG5 | c.3662C>T p.S1221F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC3L4 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- EXOC4 | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- FREM2 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GAK | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- GFI1 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GON7 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- GPAT4 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- H2AC11 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- H2BC7 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- HDAC6 | c.3250C>T p.Q1084* | Nonsense Mutation (SNP) | VAF 66/66 reads (100%) | called by muse, mutect2, varscan2
- HIBCH | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 97/182 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HLX | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHA1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGKC | c.28A>C p.I10L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- IL1RAPL1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- IL5RA | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IMPDH2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- INVS | c.2972C>T p.S991L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IRX2 | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ISLR2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, varscan2
- JMJD6 | c.942-3C>G | Splice Region (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- KCNA3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH4 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDR | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.11); called by muse, mutect2
- KLK15 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KNTC1 | c.2910G>C p.Q970H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LBHD1 | c.673G>A p.E225K (on ENST00000431002 / NM_001367940.1; = p.E199K on NM_024099.3) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- LIMA1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- LINGO3 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LUZP4 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 114/118 reads (97%) | SIFT tolerated (0.18); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MAF | c.818A>T p.E273V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- METTL14 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MOXD1 | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MYD88 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- MYO7B | c.5325G>A p.L1775= | Splice Region (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- NEXN | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NFE2L1 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKX1-1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- NOL6 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- NTF3 | c.716G>A p.W239* | Nonsense Mutation (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- NUP133 | c.2942C>T p.S981L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- NUP133 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NUSAP1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by mutect2, varscan2
- PAK1 | c.886-8G>C | Splice Region (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
- PATJ | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- PCBP1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDS5B | c.1635C>G p.F545L | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- PIK3R3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- POMK | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PON2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP1R12C | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- PRRG4 | c.239G>C p.R80T | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMA7 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRZ1 | c.4072G>C p.D1358H | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PWP1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- R3HDM2 | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 130/266 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RAI1 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RANBP6 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RARRES1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.017); called by mutect2, varscan2
- RASGRP4 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHOT1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIF1 | c.5627C>T p.S1876F | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RILP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RMI1 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- RNF135 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- SLC25A24 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC6A11 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC7A5 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9C2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 139/217 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPDYA | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SPNS1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- SPTBN2 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SRCAP | c.7648G>T p.E2550* | Nonsense Mutation (SNP) | VAF 106/193 reads (55%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | PolyPhen benign (0.046); called by muse, mutect2, varscan2
- STRBP | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- SUPT20HL2 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SUSD1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SVEP1 | c.10006G>A p.E3336K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACC3 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- TAPBP | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 99/207 reads (48%) | called by muse, mutect2, varscan2
- TAS2R20 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D15 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TBC1D22B | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- TBL2 | c.1343G>T p.*448Lext*54 | Nonstop Mutation (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- TCTEX1D4 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD9 | c.2588C>G p.S863* | Nonsense Mutation (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- TMEM70 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- TMPRSS11F | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TNKS2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TP53INP1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TRPM6 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- TTC12 | c.445-8C>T | Splice Region (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- TTC38 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TTN | c.55234G>A p.E18412K (on ENST00000591111; = p.E10988K on NM_003319.4) | Missense Mutation (SNP) | VAF 93/177 reads (53%) | PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TXNDC5 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBR2 | c.4327C>T p.H1443Y | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.052); called by muse, varscan2
- VWA8 | c.2233G>C p.E745Q | Missense Mutation (SNP) | VAF 48/49 reads (98%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR59 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- WNK1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, varscan2
- ZFHX4 | c.10607G>A p.R3536K | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.342); called by muse, mutect2
- ZFP64 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF124 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF138 | c.218C>T p.S73F (on ENST00000307355 / NM_001367572.1; = p.S47F on NM_006524.4) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF226 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF417 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- ZNF691 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 151/301 reads (50%) | called by muse, mutect2, varscan2
- ZNF7 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ZNFX1 | c.5254G>T p.E1752* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- ZP3 | c.1037C>T p.S346F (on ENST00000394857 / NM_001110354.2; = p.S295F on NM_007155.6) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, varscan2
- ZRANB3 | c.3043C>T p.H1015Y | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- A2M | c.1149C>G p.V383= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs1255168408; called by muse, mutect2, varscan2
- AATK | c.1249C>T p.L417= (on ENST00000326724 / NM_001080395.3; = p.L314= on NM_004920.2) | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV58687765; called by muse, mutect2, varscan2
- ADAMTS15 | c.942C>T p.I314= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- ADCY1 | c.3285C>G p.V1095= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV52031138; called by muse, mutect2, varscan2
- ALKBH2 | c.549C>T p.P183= | Silent (SNP) | VAF 61/113 reads (54%) | called by muse, mutect2, varscan2
- AMOT | c.1722C>T p.I574= (on ENST00000371959 / NM_001113490.1; = p.I165= on NM_133265.3) | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV59062355; called by muse, mutect2
- ANKRD35 | c.2397G>A p.T799= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- ANXA1 | c.409C>T p.L137= | Silent (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- APLP1 | c.933G>C p.L311= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2
- ARHGAP26 | c.1290C>T p.P430= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV99191625; called by muse, mutect2, varscan2
- ARHGEF2 | c.1161G>A p.V387= (on ENST00000361247 / NM_001162383.2; = p.V359= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/145 reads (31%) | called by muse, mutect2, varscan2
- ATG16L2 | c.1524G>A p.L508= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- B4GALT6 | c.660C>T p.V220= | Silent (SNP) | VAF 54/103 reads (52%) | called by muse, mutect2, varscan2
- BLNK | c.768G>A p.L256= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs781818273; called by muse, mutect2, varscan2
- CACNA1I | c.3450C>G p.V1150= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1224380685; called by muse, mutect2, varscan2
- CAMK2G | c.396C>T p.I132= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as rs1291090817, COSV59479790; called by muse, mutect2, varscan2
- CC2D1A | c.345G>A p.Q115= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV100528679; called by muse, mutect2, varscan2
- CDK14 | c.363C>T p.P121= (on ENST00000380050 / NM_001287135.2; = p.P103= on NM_012395.3) | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as rs1164971851; called by muse, mutect2, varscan2
- CDKN1C | c.270C>T p.F90= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CEP112 | c.1707G>A p.K569= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- CIDEC | c.138C>T p.R46= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs1443684622; called by muse, mutect2, varscan2
- CNTN1 | c.300C>T p.I100= | Silent (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- COG1 | c.2862C>T p.F954= | Silent (SNP) | VAF 87/170 reads (51%) | catalogued as rs766614159; called by muse, mutect2, varscan2
- COL4A3 | c.4584G>A p.L1528= | Silent (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- CSTF2 | c.18G>A p.V6= | Silent (SNP) | VAF 63/66 reads (95%) | called by muse, mutect2, varscan2
- DCLRE1C | c.72G>A p.L24= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs760707626; called by muse, mutect2, varscan2
- DDN | c.1902C>T p.L634= | Silent (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- DNAH5 | c.3606G>A p.L1202= | Silent (SNP) | VAF 64/145 reads (44%) | called by muse, mutect2, varscan2
- DOCK2 | c.1452C>G p.V484= | Silent (SNP) | VAF 74/162 reads (46%) | called by muse, mutect2, varscan2
- ECM2 | c.1350C>T p.L450= | Silent (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
- EDEM2 | c.1374C>A p.I458= | Silent (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- ERBB4 | c.1701C>T p.L567= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs1431292349; called by muse, mutect2, varscan2
- FAM83G | c.42G>A p.V14= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100524862; called by muse, mutect2, varscan2
- FANCF | c.258C>T p.L86= | Silent (SNP) | VAF 56/106 reads (53%) | catalogued as rs146352365, COSV59416996; called by muse, mutect2, varscan2
- FCN1 | c.879C>T p.L293= | Silent (SNP) | VAF 56/202 reads (28%) | catalogued as COSV65662238; called by muse, mutect2, varscan2
- FOXF2 | c.1011G>A p.A337= | Silent (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- FYB2 | c.1179G>A p.L393= | Silent (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- FZD5 | c.375C>T p.F125= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs1407775567, COSV54944839; called by muse, mutect2, varscan2
- G6PC2 | c.840G>C p.L280= | Silent (SNP) | VAF 84/184 reads (46%) | catalogued as rs1257597797; called by muse, mutect2, varscan2
- GALNT12 | c.318C>T p.Y106= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1444339435; ClinVar: likely benign; called by muse, mutect2
- GALNT12 | c.1653G>A p.A551= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs776668170, COSV100899222, COSV66662662; ClinVar: likely benign; called by muse, mutect2, varscan2
- GALNT17 | c.873G>A p.S291= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as rs376148000; called by muse, mutect2, varscan2
- GRID1 | c.342C>G p.L114= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- HSP90AA1 | c.450G>A p.V150= | Silent (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1405C>T p.L469= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs375047280; called by muse, mutect2, varscan2
- ICE2 | c.36G>A p.L12= | Silent (SNP) | VAF 73/167 reads (44%) | called by muse, mutect2, varscan2
- IER2 | c.135G>A p.E45= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs758174334, COSV52848405; called by muse, mutect2, varscan2
- IGHV1-69D | c.135A>C p.G45= | Silent (SNP) | VAF 33/55 reads (60%) | called by muse, varscan2
- IGHV4-34 | c.321G>A p.K107= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs780971935; called by muse, mutect2, varscan2
- IGSF6 | c.96C>T p.V32= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs368474150; called by muse, mutect2, varscan2
- IL12A | c.258C>T p.L86= | Silent (SNP) | VAF 66/136 reads (49%) | called by muse, mutect2, varscan2
- IL4I1 | c.729C>T p.F243= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV55578206; called by muse, mutect2, varscan2
- ITIH4 | c.552C>T p.I184= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV99819236; called by muse, mutect2, varscan2
- ITPKB | c.144C>T p.F48= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs765455655; called by muse, mutect2, varscan2
- KBTBD11 | c.1524C>T p.S508= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- KCNK1 | c.846G>C p.V282= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV64036642; called by muse, mutect2, varscan2
- KCNK13 | c.211C>T p.L71= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs766676331; called by mutect2, varscan2
- KDM6A | c.1849C>T p.L617= | Silent (SNP) | VAF 90/96 reads (94%) | called by muse, mutect2, varscan2
- KIF7 | c.1668C>T p.P556= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs559627458, COSV67997581; called by muse, mutect2, varscan2
- KLHL31 | c.1251C>T p.F417= | Silent (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- KNOP1 | c.594G>A p.Q198= | Silent (SNP) | VAF 115/236 reads (49%) | called by muse, mutect2, varscan2
- KPNA7 | c.214C>T p.L72= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- KRT18 | c.1284G>C p.L428= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV101184041, COSV101184043; called by muse, mutect2, varscan2
- KRT74 | c.363C>G p.L121= | Silent (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- LAX1 | c.61C>T p.L21= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as COSV65849530; called by muse, mutect2, varscan2
- LTB4R2 | c.456C>A p.L152= (on ENST00000528054; = p.L121= on NM_019839.5) | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- MEF2D | c.417C>T p.N139= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs1469173013; called by muse, mutect2, varscan2
- METTL9 | c.75G>A p.R25= | Silent (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- MLLT3 | c.1551G>A p.L517= | Silent (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- MOBP | c.99C>G p.L33= | Silent (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- MOV10L1 | c.3222G>A p.E1074= | Silent (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- MRPL54 | c.111G>A p.K37= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- MYH7B | c.1785G>A p.K595= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs765408332; called by muse, mutect2, varscan2
- MYL6B | c.626G>A p.*209= | Silent (SNP) | VAF 68/147 reads (46%) | called by muse, mutect2, varscan2
- MYO18A | c.4488C>T p.F1496= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs916156128; called by muse, mutect2, varscan2
- MYOCD | c.1557G>A p.K519= | Silent (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- NCLN | c.774C>G p.L258= | Silent (SNP) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- NLRP13 | c.1218G>A p.E406= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as COSV61622436; called by muse, mutect2, varscan2
- NPAS1 | c.1641G>A p.A547= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- NRXN2 | c.4953C>T p.L1651= | Silent (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- NUP98 | c.4128C>T p.T1376= (on ENST00000359171 / NM_001365126.1; = p.T1359= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs1283489600; called by muse, mutect2, varscan2
- OBSL1 | c.5184G>A p.V1728= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- PCDHA4 | c.144C>T p.I48= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV100793137; called by muse, mutect2, varscan2
- PIK3C2G | c.807G>A p.G269= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs374623477, COSV56800341; called by muse, mutect2
- PLCD4 | c.1785G>A p.Q595= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV68743300; called by muse, mutect2, varscan2
- POGK | c.1062C>T p.D354= | Silent (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- PRKDC | c.7179G>A p.L2393= | Silent (SNP) | VAF 88/194 reads (45%) | catalogued as COSV58067106; called by muse, mutect2, varscan2
- PRPF4B | c.3006C>T p.F1002= | Silent (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- PRR12 | c.2364C>T p.A788= (on ENST00000615927; = p.A1609= on NM_020719.3) | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs1039772078; called by muse, mutect2, varscan2
- PTPN6 | c.210G>A p.A70= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs782575533, COSV59686136; called by muse, mutect2, varscan2
- RAB39B | c.183G>A p.Q61= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as COSV65624529; called by mutect2, varscan2
- RASAL2 | c.387G>A p.L129= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV62710466; called by muse, mutect2, varscan2
- RFX6 | c.933C>A p.I311= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV60585189; called by muse, mutect2, varscan2
- RPS6KL1 | c.297G>A p.V99= | Silent (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- RUSC2 | c.2700G>A p.R900= | Silent (SNP) | VAF 55/103 reads (53%) | called by muse, mutect2, varscan2
- SCYL2 | c.1044G>A p.Q348= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV62567710; called by muse, mutect2, varscan2
- SDCBP2 | c.456C>T p.L152= (on ENST00000339987 / NM_001199784.1; = p.L67= on NM_015685.5) | Silent (SNP) | VAF 76/147 reads (52%) | catalogued as rs776982455, COSV60591471; called by muse, mutect2, varscan2
- SEMA4B | c.2172C>G p.L724= | Silent (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- SIGLEC15 | c.636G>A p.R212= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- SIK3 | c.3975G>C p.L1325= (on ENST00000445177 / NM_001366686.2; = p.L1283= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- SLC35F1 | c.114G>A p.G38= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- SNTG1 | c.945C>G p.L315= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- SNX13 | c.2787C>T p.F929= | Silent (SNP) | VAF 77/163 reads (47%) | catalogued as rs775876431; called by muse, mutect2, varscan2
- SPATA20 | c.37C>T p.L13= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs535515050; called by muse, varscan2
- SPEG | c.7326G>A p.G2442= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV56682348; called by muse, mutect2, varscan2
- STIM1 | c.12C>T p.C4= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as rs752778021; called by muse, mutect2, varscan2
- SYNE3 | c.2307C>T p.F769= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- TAB2 | c.2079C>T p.F693= | Silent (SNP) | VAF 96/206 reads (47%) | catalogued as rs773943431, COSV53853286; called by muse, mutect2, varscan2
- TAS2R50 | c.57C>T p.L19= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as rs559886995, COSV67861705; called by muse, mutect2, varscan2
- TCERG1L | c.423C>T p.L141= | Silent (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- TGM7 | c.399G>A p.P133= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs557114118; called by muse, mutect2, varscan2
- TIMMDC1 | c.36C>G p.L12= | Silent (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- TMEM200C | c.753C>T p.L251= | Silent (SNP) | VAF 22/44 reads (50%) | called by muse, varscan2
- TPGS2 | c.352C>T p.L118= | Silent (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.15C>T p.I5= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs748351026, COSV51935815, COSV51936042; called by muse, mutect2
- TTN | c.100986G>A p.L33662= (on ENST00000591111; = p.L26238= on NM_003319.4) | Silent (SNP) | VAF 93/212 reads (44%) | catalogued as COSV100601594; called by muse, mutect2, varscan2
- TWSG1 | c.438G>A p.Q146= | Silent (SNP) | VAF 62/148 reads (42%) | catalogued as COSV100039394, COSV50814837; called by muse, mutect2, varscan2
- WDR46 | c.231G>A p.K77= | Silent (SNP) | VAF 67/147 reads (46%) | called by muse, mutect2, varscan2
- YIF1A | c.264G>A p.V88= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- ZDHHC13 | c.1179G>A p.K393= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- AC007557.3 | n.2779C>T | RNA (SNP) | VAF 50/102 reads (49%) | catalogued as rs866462252; called by muse, mutect2, varscan2
- AC025279.2 | n.456C>T | RNA (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- AC027644.4 | c.397+43250G>A | Intron (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2
- AC105942.1 | n.1134G>A | RNA (SNP) | VAF 30/64 reads (47%) | catalogued as rs71652593; called by muse, mutect2, varscan2
- AC108676.1 | n.723C>T | RNA (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- ACAD9 | c.150+121G>A | Intron (SNP) | VAF 30/57 reads (53%) | catalogued as rs1463384076; called by muse, mutect2, varscan2
- ACBD6 | chr1:180502595 G>A | 5'Flank (SNP) | VAF 38/58 reads (66%) | catalogued as rs943659601; called by muse, mutect2, varscan2
- ACER2 | c.-30G>A | 5'UTR (SNP) | VAF 20/33 reads (61%) | catalogued as rs757923845; called by muse, mutect2, varscan2
- ACER2 | c.*1463G>A | 3'UTR (SNP) | VAF 9/14 reads (64%) | called by mutect2, varscan2
- ACTR2 | c.-11C>T | 5'UTR (SNP) | VAF 13/31 reads (42%) | catalogued as rs946622248, COSV99573754; called by muse, mutect2, varscan2
- ADAM1A | chr12:111901682 G>C | 3'Flank (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- ADAR | c.-935G>A | 5'UTR (SNP) | VAF 24/74 reads (32%) | catalogued as rs1297318149, COSV52719579; called by muse, varscan2
- ADD2 | c.-316C>T | 5'UTR (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100035732; called by muse, mutect2, varscan2
- AFDN | chr6:167825593 C>G | 5'Flank (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- AIFM1 | c.*28C>T | 3'UTR (SNP) | VAF 100/104 reads (96%) | catalogued as rs755390188; called by muse, mutect2, varscan2
- AL158050.1 | n.380G>A | RNA (SNP) | VAF 35/80 reads (44%) | catalogued as rs201089702; called by muse, mutect2, varscan2
- AL162431.2 | n.166C>T | RNA (SNP) | VAF 29/64 reads (45%) | catalogued as rs1338662568; called by muse, mutect2, varscan2
- AL353622.2 | chr1:28246658 C>A | 5'Flank (SNP) | VAF 66/131 reads (50%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.-162G>A | 5'UTR (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.1043-9663C>T | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- ALOX12B | c.755-46G>A | Intron (SNP) | VAF 35/68 reads (51%) | catalogued as COSV59871725; called by muse, mutect2, varscan2
- AMZ1 | c.*2494C>T | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- ANAPC7 | c.*588C>T | 3'UTR (SNP) | VAF 37/75 reads (49%) | catalogued as rs990312927; called by muse, mutect2, varscan2
- ANK1 | c.*1345C>T | 3'UTR (SNP) | VAF 79/162 reads (49%) | catalogued as rs562500715; called by muse, mutect2, varscan2
- ANKRD31 | c.-171C>T | 5'UTR (SNP) | VAF 30/64 reads (47%) | catalogued as COSV57164547; called by muse, mutect2, varscan2
- ANO5 | c.-92G>A | 5'UTR (SNP) | VAF 51/111 reads (46%) | catalogued as COSV100201419, COSV100201603; called by muse, mutect2, varscan2
- ANXA2R | c.-333G>A | 5'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- AP000769.1 | n.151A>C | RNA (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- AP4S1 | c.306+5627G>C | Intron (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- APBB2 | c.*5028G>A | 3'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- APMAP | chr20:24992978 G>A | 5'Flank (SNP) | VAF 8/21 reads (38%) | catalogued as rs1183474892; called by muse, mutect2, varscan2
- APOBEC3B | c.1135-20C>T | Intron (SNP) | VAF 65/127 reads (51%) | called by muse, mutect2, varscan2
- APP | c.*541G>C | 3'UTR (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- ARF1 | c.*771G>A | 3'UTR (SNP) | VAF 58/178 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.384+8869C>T | Intron (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.-163G>A | 5'UTR (SNP) | VAF 58/177 reads (33%) | catalogued as rs1228748570; called by muse, mutect2, varscan2
- ARHGAP32 | c.*244G>A | 3'UTR (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- ARHGEF38 | c.*1573C>G | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- ARHGEF7 | c.*1300T>C | 3'UTR (SNP) | VAF 25/27 reads (93%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918432 G>A | 5'Flank (SNP) | VAF 33/62 reads (53%) | catalogued as COSV99065278; called by muse, mutect2, varscan2
- ARL6IP1 | c.36+75C>T | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- ARPC5L | c.*660C>T | 3'UTR (SNP) | VAF 41/129 reads (32%) | catalogued as rs936329963; called by muse, mutect2, varscan2
- ASPH | c.104-5658C>T | Intron (SNP) | VAF 97/176 reads (55%) | called by muse, mutect2, varscan2
- ATF6 | chr1:161766158 C>T | 5'Flank (SNP) | VAF 12/57 reads (21%) | catalogued as rs944117883; called by muse, mutect2, varscan2
- ATL1 | c.34+190C>T | Intron (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- ATP2B4 | c.*3222G>C | 3'UTR (SNP) | VAF 50/79 reads (63%) | called by muse, mutect2, varscan2
- ATP6V0C | c.-106C>T | 5'UTR (SNP) | VAF 10/12 reads (83%) | catalogued as rs1024402919; called by muse, mutect2, varscan2
- ATP6V1G3 | c.*80G>A | 3'UTR (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2782-49C>T | Intron (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- B4GALT3 | c.-161+399G>A | Intron (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- B4GALT4 | c.902+289T>A | Intron (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*666C>T | 3'UTR (SNP) | VAF 68/126 reads (54%) | called by muse, mutect2, varscan2
- BHLHE41 | c.*1303G>A | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- BIN2 | c.-53C>T | 5'UTR (SNP) | VAF 18/30 reads (60%) | called by mutect2, varscan2
- BMP6 | c.*1052G>A | 3'UTR (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- BPIFA3 | c.-99C>T | 5'UTR (SNP) | VAF 65/124 reads (52%) | called by muse, mutect2, varscan2
- C1orf162 | c.*229G>A | 3'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- C8orf34 | c.328-486G>A | Intron (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- C8orf86 | n.2145G>A | RNA (SNP) | VAF 13/14 reads (93%) | catalogued as rs1192151967; called by muse, mutect2, varscan2
- C9orf163 | n.494C>T | RNA (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- C9orf64 | c.-61G>A | 5'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100123499; called by muse, mutect2, varscan2
- CADPS2 | c.*139A>T | 3'UTR (SNP) | VAF 81/157 reads (52%) | called by muse, mutect2, varscan2
- CALB2 | c.172-166G>A | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CALR | c.-9C>T | 5'UTR (SNP) | VAF 29/57 reads (51%) | catalogued as rs370935055, COSV100109009; called by muse, mutect2, varscan2
- CAMKMT | c.377-154628C>T | Intron (SNP) | VAF 79/161 reads (49%) | catalogued as rs914067321; called by muse, mutect2, varscan2
- CCDC113 | c.*3324G>A | 3'UTR (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- CCND3 | c.*94G>A | 3'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- CCNDBP1 | c.-15C>T | 5'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- CD274 | c.*410G>A | 3'UTR (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- CD276 | c.1504+119G>A | Intron (SNP) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- CD2AP | c.*1848_*1859delinsCA | 3'UTR (DEL) | VAF 39/73 reads (53%) | called by pindel, varscan2*
- CD80 | c.*685C>T | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- CDH12 | c.*286C>G | 3'UTR (SNP) | VAF 26/57 reads (46%) | catalogued as rs1468942359; called by muse, mutect2, varscan2
- CDH19 | c.1336+2353C>A | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- CDKN1C | c.*21G>A | 3'UTR (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- CDR2L | c.-55C>T | 5'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- CFAP20DC | c.1593+1880G>C | Intron (SNP) | VAF 34/68 reads (50%) | catalogued as rs984385694; called by muse, mutect2, varscan2
- CFAP20DC | c.1593+1781G>A | Intron (SNP) | VAF 27/45 reads (60%) | catalogued as rs955915861; called by muse, mutect2, varscan2
- CHORDC1 | c.*1126G>A | 3'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- CHRNE | c.*212C>T | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- CLEC4E | c.*688C>G | 3'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as rs1349282447; called by muse, mutect2, varscan2
- CNIH4 | c.*3374G>A | 3'UTR (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- CNN3 | c.-191G>A | 5'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- COPA | c.1219+45C>T | Intron (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- CPM | c.*1220G>C | 3'UTR (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- CRTC2 | c.-50G>A | 5'UTR (SNP) | VAF 8/30 reads (27%) | catalogued as rs777661866, COSV100135283, COSV100135674; called by muse, mutect2, varscan2
- CRYBG3 | c.*1519G>C | 3'UTR (SNP) | VAF 28/66 reads (42%) | catalogued as rs1029301533; called by muse, mutect2
- CSH1 | c.456+122C>G | Intron (SNP) | VAF 76/124 reads (61%) | called by muse, mutect2, varscan2
- CSNK1D | c.737-59G>A | Intron (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- CWC27 | c.938+4012G>C | Intron (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- CXADR | c.-73G>A | 5'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- CYB561D2 | c.-91-98C>T | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CYB5R4 | chr6:83859660 C>T | 5'Flank (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- CYBB | c.*15G>A | 3'UTR (SNP) | VAF 101/106 reads (95%) | called by muse, mutect2, varscan2
- CYP2G2P | n.1197C>T | RNA (SNP) | VAF 52/90 reads (58%) | called by muse, mutect2, varscan2
- CYRIA | c.*557C>T | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- DALRD3 | chr3:49022084 G>A | 5'Flank (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- DBNDD1 | c.*960G>A | 3'UTR (SNP) | VAF 25/53 reads (47%) | catalogued as rs538739522; called by muse, mutect2, varscan2
- DCP2 | c.-99C>T | 5'UTR (SNP) | VAF 51/97 reads (53%) | catalogued as rs529002689, COSV101203972; called by muse, mutect2, varscan2
- DDX3X | c.*1450C>G | 3'UTR (SNP) | VAF 50/52 reads (96%) | called by muse, mutect2, varscan2
- DENND2D | c.-69C>T | 5'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- DEPDC1 | chr1:68497195 C>T | 5'Flank (SNP) | VAF 20/34 reads (59%) | catalogued as rs1293720505, COSV63958016; called by muse, mutect2, varscan2
- DERL2 | chr17:5486190 C>T | 5'Flank (SNP) | VAF 23/43 reads (53%) | catalogued as rs572712487; called by muse, mutect2, varscan2
- DMPK | c.253-32G>A | Intron (SNP) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- DNAAF4 | c.-198C>T | 5'UTR (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- DNAH14 | c.6033+1075C>T | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- DNAJB2 | c.-37+139G>A | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- DPCD | c.*119G>C | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- DPY19L4 | c.611+4603G>A | Intron (SNP) | VAF 101/193 reads (52%) | called by muse, varscan2
- DUS4L | c.357-181G>A | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- DUSP23 | c.*181G>T | 3'UTR (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- DYNAP | c.*25_*29delinsTAA | 3'UTR (DEL) | VAF 106/256 reads (41%) | called by pindel, varscan2*
- DYNC2LI1 | c.321-783C>G | Intron (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.321-542C>G | Intron (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- E4F1 | c.157+60G>A | Intron (SNP) | VAF 71/72 reads (99%) | called by muse, mutect2, varscan2
- EBAG9 | c.-15-345C>T | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- EBF2 | c.*1749C>T | 3'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- EHHADH | c.-26G>A | 5'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- EIF4E | c.-57C>T | 5'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- EIF4E2 | chr2:232550569 G>A | 5'Flank (SNP) | VAF 20/50 reads (40%) | catalogued as rs573958077; called by muse, mutect2, varscan2
- EMC8 | c.-185G>A | 5'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- ENO2 | c.*297G>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2
- ENSA | c.351-1383C>T | Intron (SNP) | VAF 71/216 reads (33%) | called by muse, mutect2, varscan2
- EPB41L4A | chr5:112161772 G>A | 3'Flank (SNP) | VAF 19/30 reads (63%) | called by mutect2, varscan2
- ERAP1 | c.*42G>C | 3'UTR (SNP) | VAF 50/105 reads (48%) | called by muse, mutect2, varscan2
- ERGIC3 | c.160-18G>A | Intron (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.1284+84C>T | Intron (SNP) | VAF 13/25 reads (52%) | catalogued as rs756253676; called by muse, mutect2, varscan2
- EYA1 | c.*571A>T | 3'UTR (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- F2 | chr11:46719209 C>G | 5'Flank (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- FAM110C | c.*931G>A | 3'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- FAM161B | c.*793C>G | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- FAM53B | c.*3075G>A | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- FANCI | c.157+113G>C | Intron (SNP) | VAF 22/52 reads (42%) | called by mutect2, varscan2
- FASTKD3 | c.1769+42G>A | Intron (SNP) | VAF 11/21 reads (52%) | catalogued as rs558049896; called by muse, mutect2, varscan2
- FAT3 | c.*4657G>A | 3'UTR (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- FBLN7 | c.*401G>A | 3'UTR (SNP) | VAF 23/47 reads (49%) | catalogued as rs1462944215; called by muse, mutect2, varscan2
- FBN2 | c.-239C>T | 5'UTR (SNP) | VAF 24/55 reads (44%) | catalogued as rs1355121806; called by muse, mutect2, varscan2
- FBXO3 | c.1239+2108G>C | Intron (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- FBXO42 | c.*3026G>C | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- FCRLA | c.-181C>T | 5'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.-73-7070C>T | Intron (SNP) | VAF 8/8 reads (100%) | called by muse, mutect2, varscan2
- FOSL2 | c.*1313C>G | 3'UTR (SNP) | VAF 77/122 reads (63%) | called by muse, mutect2, varscan2
- FOXA2 | c.-1-199G>A | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- FOXF2 | c.*653G>A | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3219G>C | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- FTH1 | c.115-17C>T | Intron (SNP) | VAF 63/148 reads (43%) | catalogued as rs772405543; called by muse, mutect2, varscan2
- GAB2 | c.-35C>T | 5'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+19330G>A | Intron (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- GALNT15 | c.*1751C>G | 3'UTR (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- GATA4 | chr8:11762306 G>A | 3'Flank (SNP) | VAF 28/31 reads (90%) | called by muse, mutect2, varscan2
- GGCT | c.*346C>T | 3'UTR (SNP) | VAF 33/93 reads (35%) | catalogued as COSV50040856; called by muse, mutect2, varscan2
- GIGYF1 | c.-78C>T | 5'UTR (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- GIGYF2 | c.*578G>C | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- GOLIM4 | c.-68G>A | 5'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- GOLM2 | c.-66G>A | 5'UTR (SNP) | VAF 58/111 reads (52%) | called by muse, mutect2, varscan2
- GPAT2 | c.2150-13C>G | Intron (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- GPR153 | c.*932C>T | 3'UTR (SNP) | VAF 57/106 reads (54%) | called by muse, mutect2, varscan2
- GPRC5A | c.*3962G>A | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- GSE1 | c.*1889C>T | 3'UTR (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+549C>T | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- GSTK1 | c.-57C>T | 5'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- GTF2A1 | c.*1901C>T | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- GTF2F2 | c.-63C>T | 5'UTR (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1968G>A | RNA (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- H3C10 | c.*89C>T | 3'UTR (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- HAAO | c.-10C>T | 5'UTR (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99685500; called by muse, mutect2, varscan2
- HEBP1 | chr12:13001295 C>T | 5'Flank (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- HES2 | c.*1847G>C | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- HGF | c.625+260G>A | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- HGS | c.37+76G>A | Intron (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- HIF1AN | c.*137C>T | 3'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- HIVEP3 | c.*1881C>T | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2
- HNRNPU | c.634+876C>T | Intron (SNP) | VAF 54/195 reads (28%) | catalogued as rs1032109992, COSV99310844; called by muse, mutect2, varscan2
- HOXB2 | c.*122G>A | 3'UTR (SNP) | VAF 60/124 reads (48%) | catalogued as rs1287356426, COSV100344594; called by muse, mutect2, varscan2
- HTR1A | c.*210G>C | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2
- IDH3A | c.*2575G>A | 3'UTR (SNP) | VAF 72/123 reads (59%) | called by muse, mutect2, varscan2
- IER2 | c.-114C>T | 5'UTR (SNP) | VAF 14/26 reads (54%) | called by mutect2, varscan2
- IGDCC3 | c.409+19345G>A | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- IGSF11 | c.-162C>T | 5'UTR (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- ING5 | c.*2188C>T | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- INO80D | c.*8155C>G | 3'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- INSYN2A | c.*934G>A | 3'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as rs900845161; called by muse, mutect2, varscan2
- IP6K1 | c.*623C>T | 3'UTR (SNP) | VAF 39/93 reads (42%) | catalogued as rs1452710900; called by muse, mutect2, varscan2
- IST1 | c.-61G>A | 5'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- ITGA10 | c.*696C>T | 3'UTR (SNP) | VAF 15/43 reads (35%) | catalogued as rs759308128, COSV100994788; called by muse, mutect2, varscan2
- ITPRID2 | c.1486+542C>T | Intron (SNP) | VAF 101/210 reads (48%) | called by muse, mutect2, varscan2
- IYD | c.*7568C>T | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- JUP | c.*660C>G | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- KIF26B | c.*387C>T | 3'UTR (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- KIF3B | c.*2025G>T | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- KIFC3 | c.316-34G>A | Intron (SNP) | VAF 21/44 reads (48%) | catalogued as rs1555609344; called by muse, mutect2, varscan2
- KLF3 | c.*2856G>T | 3'UTR (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- KLHL36 | c.*1730C>T | 3'UTR (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- KPNA6 | c.*3648C>G | 3'UTR (SNP) | VAF 55/100 reads (55%) | catalogued as rs987866750; called by muse, mutect2, varscan2
- LAMC2 | c.3328+208G>A | Intron (SNP) | VAF 45/73 reads (62%) | called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407812 G>A | 5'Flank (SNP) | VAF 47/106 reads (44%) | catalogued as COSV56679640; called by muse, mutect2
- LCLAT1 | c.479-9529G>A | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as COSV58374368; called by muse, mutect2, varscan2
- LETMD1 | chr12:51048065 G>A | 5'Flank (SNP) | VAF 36/78 reads (46%) | catalogued as rs945304786; called by muse, mutect2, varscan2
- LGALS9 | chr17:27629853 C>G | 5'Flank (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- LGI4 | c.1299+146C>G | Intron (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- LIMD1 | c.*7361C>T | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- LINC00242 | n.454G>A | RNA (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- LINC01565 | n.1833G>A | RNA (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- LINC02410 | n.185G>A | RNA (SNP) | VAF 61/119 reads (51%) | catalogued as rs1377304015; called by muse, mutect2, varscan2
- LMBR1L | c.-137G>A | 5'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- LMBR1L | c.-255G>A | 5'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- LORICRIN | c.*155C>T | 3'UTR (SNP) | VAF 46/136 reads (34%) | catalogued as COSV100907293; called by muse, mutect2, varscan2
- LRRC14 | c.*2090C>T | 3'UTR (SNP) | VAF 60/145 reads (41%) | catalogued as COSV99468439; called by muse, mutect2, varscan2
- LRRC23 | c.*170C>T | 3'UTR (SNP) | VAF 53/99 reads (54%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132379878 G>C | 3'Flank (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- LRRC57 | c.-324G>A | 5'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- LRRC7 | c.647+35376C>T | Intron (SNP) | VAF 52/94 reads (55%) | called by muse, mutect2, varscan2
- LTB | c.162+137C>G | Intron (SNP) | VAF 28/62 reads (45%) | catalogued as rs186447095, COSV53001762; called by muse, mutect2, varscan2
- LZTFL1 | c.*2916G>A | 3'UTR (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11145G>A | Intron (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- MAGEB4 | c.*79G>A | 3'UTR (SNP) | VAF 45/46 reads (98%) | catalogued as rs1214630435, COSV100975068; called by muse, mutect2, varscan2
- MAGEC3 | c.910-533G>A | Intron (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- MAN2A1 | c.-491C>T | 5'UTR (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- MARCHF8 | c.*240C>T | 3'UTR (SNP) | VAF 35/71 reads (49%) | catalogued as rs960378926; called by muse, mutect2, varscan2
- MARCHF9 | c.514-135G>A | Intron (SNP) | VAF 81/194 reads (42%) | catalogued as rs572356919; called by muse, mutect2, varscan2
- MARVELD1 | c.*269G>A | 3'UTR (SNP) | VAF 50/105 reads (48%) | catalogued as rs940996057; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71644758 C>T | 3'Flank (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- MDFIC | c.-107-45C>T | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- MDGA1 | c.-541C>T | 5'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- MECOM | chr3:169084300 T>C | 3'Flank (SNP) | VAF 30/70 reads (43%) | catalogued as rs891444448; called by muse, mutect2, varscan2
- MED11 | c.-36G>C | 5'UTR (SNP) | VAF 15/31 reads (48%) | catalogued as COSV53411504, COSV99543552; called by muse, mutect2
- MED9 | c.*656C>G | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- MEF2D | c.*2220G>A | 3'UTR (SNP) | VAF 97/163 reads (60%) | called by muse, mutect2, varscan2
- MEIS3 | c.859-25G>A | Intron (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100520526; called by muse, mutect2, varscan2
- MESP1 | c.*308C>T | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- METAP1D | c.*857G>C | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- MIER3 | c.*1003G>A | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- MKX | c.-27C>T | 5'UTR (SNP) | VAF 26/43 reads (60%) | catalogued as rs1170985953; called by muse, mutect2, varscan2
- MLEC | c.*1656G>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- MLEC | c.*1795G>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- MLXIPL | c.*10G>C | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- MOB3B | c.*728G>A | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- MPV17L2 | c.*315C>T | 3'UTR (SNP) | VAF 98/176 reads (56%) | called by muse, mutect2, varscan2
- MRPL40 | c.-18G>A | 5'UTR (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- MSANTD2 | c.511-784G>A | Intron (SNP) | VAF 42/94 reads (45%) | catalogued as rs552103174; called by muse, mutect2, varscan2
- MSL3 | c.1172-1014G>A | Intron (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- MTDH | c.*3819G>A | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- MTHFD1 | c.1674+45G>C | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- MYO5A | c.*2994C>G | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- NACA | c.71-1982C>T | Intron (SNP) | VAF 39/73 reads (53%) | catalogued as rs748498220; called by muse, mutect2, varscan2
- NCBP1 | c.*884G>A | 3'UTR (SNP) | VAF 65/103 reads (63%) | called by muse, mutect2, varscan2
- NF2 | c.*3186C>T | 3'UTR (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- NFATC2IP | c.*1431C>T | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- NFIB | c.-372C>T | 5'UTR (SNP) | VAF 28/58 reads (48%) | catalogued as rs1475720232; called by muse, mutect2, varscan2
- NGDN | chr14:23478529 C>T | 3'Flank (SNP) | VAF 41/72 reads (57%) | called by muse, mutect2, varscan2
- NGLY1 | c.1004-182C>G | Intron (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- NIM1K | c.-557C>G | 5'UTR (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- NLGN1 | c.493+501A>G | Intron (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- NOX4 | c.*216G>A | 3'UTR (SNP) | VAF 82/185 reads (44%) | called by muse, mutect2, varscan2
- NPL | c.*701C>T | 3'UTR (SNP) | VAF 110/337 reads (33%) | called by muse, mutect2, varscan2
- NQO2 | c.-65G>T | 5'UTR (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- NRG4 | c.*251C>T | 3'UTR (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+3541G>C | Intron (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+1885C>G | Intron (SNP) | VAF 79/149 reads (53%) | called by muse, mutect2, varscan2
- NUFIP2 | c.-49G>A | 5'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2
- OCLN | c.*235G>A | 3'UTR (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- ODAPH | chr4:75565718 C>T | 3'Flank (SNP) | VAF 48/80 reads (60%) | called by muse, mutect2, varscan2
- ODF3 | c.534+19G>A | Intron (SNP) | VAF 66/144 reads (46%) | catalogued as rs759653772; called by muse, mutect2, varscan2
- ONECUT1 | c.1105+7902C>T | Intron (SNP) | VAF 84/164 reads (51%) | called by muse, mutect2, varscan2
- OR2A12 | c.-47G>A | 5'UTR (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- OR51A4 | chr11:4943925 G>A | 3'Flank (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- OR5V1 | c.-41C>G | 5'UTR (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
- OSBPL7 | c.256-21C>T | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2
- OTUD7B | c.*2047C>T | 3'UTR (SNP) | VAF 49/150 reads (33%) | catalogued as rs942611192; called by muse, mutect2, varscan2
- P2RY8 | c.*365C>G | 3'UTR (SNP) | VAF 40/43 reads (93%) | called by muse, mutect2, varscan2
- PACRG | c.613+101392G>A | Intron (SNP) | VAF 45/108 reads (42%) | catalogued as rs977343346; called by muse, mutect2, varscan2
- PAN2 | chr12:56316326 G>A | 3'Flank (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PARVB | c.*275C>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- PBK | c.*354C>T | 3'UTR (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- PCBP3 | c.*317G>A | 3'UTR (SNP) | VAF 58/183 reads (32%) | called by muse, mutect2, varscan2
- PDE11A | c.*730G>C | 3'UTR (SNP) | VAF 48/87 reads (55%) | called by muse, mutect2, varscan2
- PDIA3 | c.-94G>A | 5'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- PDLIM2 | chr8:22595302 C>T | 3'Flank (SNP) | VAF 38/39 reads (97%) | catalogued as rs1434621726; called by muse, mutect2, varscan2
- PEX13 | c.92+357G>A | Intron (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- PFKM | c.1127+40G>A | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- PGR | c.*8295G>A | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- PHC3 | c.378+935C>G | Intron (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- PHOX2A | c.-7C>T | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PHYH | chr10:13300071 C>T | 5'Flank (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- PIK3R1 | c.917-3541C>T | Intron (SNP) | VAF 91/159 reads (57%) | called by muse, mutect2, varscan2
- PIM3 | c.-57G>A | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- PLCL1 | c.-269C>T | 5'UTR (SNP) | VAF 85/159 reads (53%) | called by muse, varscan2
- PLD3 | chr19:40348540 G>A | 5'Flank (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.243+69G>A | Intron (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- POF1B | c.*1434C>T | 3'UTR (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- POGK | c.*51G>A | 3'UTR (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- POLR1B | c.*306C>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- POMZP3 | c.*99C>T | 3'UTR (SNP) | VAF 11/17 reads (65%) | called by mutect2, varscan2
- PPARGC1B | c.*5837G>C | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- PPM1A | c.*1926C>T | 3'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- PPP1R1B | chr17:39622197 G>C | 5'Flank (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- PPP3R1 | c.-339G>A | 5'UTR (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- PPP3R2 | c.*235A>T | 3'UTR (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- PRPF3 | c.1844-136G>C | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2
- PRR34 | n.222C>A | RNA (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- RAB9A | c.*1040C>T | 3'UTR (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.-52G>A | 5'UTR (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- RALGPS1 | c.*3561G>A | 3'UTR (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
- RANBP2 | c.*1158T>C | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- RAPSN | c.-65C>T | 5'UTR (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- RASAL2 | chr1:178093202 C>T | 5'Flank (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- RASAL2 | c.-25C>T | 5'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as rs779061978; called by muse, mutect2, varscan2
- RASL10B | c.*1157C>T | 3'UTR (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- RBL1 | c.*1807T>G | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- RCC1L | chr7:75073854 G>A | 5'Flank (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- REXO4 | c.*36G>A | 3'UTR (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100905790; called by muse, mutect2, varscan2
- RGL2 | c.157-408G>A | Intron (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- RGP1 | c.*1437G>A | 3'UTR (SNP) | VAF 35/53 reads (66%) | called by muse, mutect2, varscan2
- RGS5 | c.*3381G>A | 3'UTR (SNP) | VAF 54/158 reads (34%) | called by muse, mutect2, varscan2
- RHOT1 | c.1739+2912C>T | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.694C>T | RNA (SNP) | VAF 27/215 reads (13%) | catalogued as rs1178912919; called by muse, mutect2, varscan2
- RILPL1 | c.-10G>A | 5'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- RIMKLB | c.*2497G>C | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- RNF144A | c.*2246G>A | 3'UTR (SNP) | VAF 27/66 reads (41%) | catalogued as rs558576908; called by muse, mutect2, varscan2
- RNF145 | chr5:159209886 G>A | 5'Flank (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- RNF169 | c.*3730C>T | 3'UTR (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- RNF215 | c.286-52C>T | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as rs1233454534; called by muse, mutect2, varscan2
- RNF217 | c.*7025C>T | 3'UTR (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- RNF217 | c.*9524G>A | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs1219353514; called by muse, mutect2, varscan2
- RNF40 | c.*2164C>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2
- ROR1 | c.-242G>A | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- RP2 | c.*138G>A | 3'UTR (SNP) | VAF 46/46 reads (100%) | called by muse, mutect2, varscan2
- RPL23A | c.25+326C>T | Intron (SNP) | VAF 60/118 reads (51%) | catalogued as rs1335642594; called by muse, mutect2, varscan2
- RPL9 | c.-2+20C>T | Intron (SNP) | VAF 63/120 reads (53%) | catalogued as rs1297145910; called by muse, mutect2, varscan2
- RPS19 | c.172+106G>A | Intron (SNP) | VAF 67/126 reads (53%) | called by muse, mutect2
- RPS28 | c.87+25G>T | Intron (SNP) | VAF 38/85 reads (45%) | catalogued as rs763224977; called by muse, mutect2, varscan2
- RUNX2 | c.59-81C>G | Intron (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- SAMM50 | c.*71G>A | 3'UTR (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- SAPCD2 | c.-57C>T | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- SCIN | chr7:12570526 C>G | 5'Flank (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- SCLT1 | c.290+1012C>T | Intron (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- SCML4 | c.*650G>A | 3'UTR (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- SEC13 | c.3+43G>A | Intron (SNP) | VAF 33/71 reads (46%) | catalogued as rs1181171829, COSV59505451; called by muse, mutect2, varscan2
- SEC1P | n.448C>T | RNA (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- SECISBP2 | chr9:89360824 G>C | 3'Flank (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- SEL1L | c.*1679C>T | 3'UTR (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- SENP6 | c.-459G>A | 5'UTR (SNP) | VAF 42/77 reads (55%) | called by muse, mutect2, varscan2
- SERPINA13P | n.637C>T | RNA (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- SERPINA9 | chr14:94476230 C>T | 5'Flank (SNP) | VAF 183/367 reads (50%) | called by muse, mutect2, varscan2
- SETD9 | c.98+339G>A | Intron (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- SGK1 | c.786+83A>T | Intron (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- SH2D4B | chr10:80645302 C>T | 3'Flank (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- SHFL | c.235-40G>A | Intron (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- SHISA6 | c.*121G>C | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- SLC10A4 | c.591-27G>A | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*1107C>T | 3'UTR (SNP) | VAF 28/52 reads (54%) | catalogued as rs1376368035; called by muse, varscan2
- SLC11A2 | c.*1101C>G | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, varscan2
- SLC15A1 | c.*155_*159dup | 3'UTR (INS) | VAF 19/26 reads (73%) | called by mutect2, varscan2*
- SLC16A14 | c.*608C>T | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- SLC25A51P4 | n.1463+563G>A | Intron (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- SLC35G3 | c.*441C>T | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*5970G>A | 3'UTR (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- SLC4A7 | c.-42G>A | 5'UTR (SNP) | VAF 12/23 reads (52%) | catalogued as COSV66257805; called by muse, mutect2, varscan2
- SLC51A | c.*67C>A | 3'UTR (SNP) | VAF 91/185 reads (49%) | catalogued as COSV53060804; called by muse, mutect2, varscan2
- SLC52A1 | c.1011-23G>A | Intron (SNP) | VAF 75/154 reads (49%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*1607C>G | 3'UTR (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928348 G>A | 3'Flank (SNP) | VAF 24/56 reads (43%) | catalogued as rs766415453; called by muse, mutect2, varscan2
- SMAD3 | c.*2178C>T | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- SMAP2 | c.*630C>T | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- SMG7 | c.2742+905G>A | Intron (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100750092; called by muse, mutect2, varscan2
- SMPD4BP | n.898C>A | RNA (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- SP140 | c.-109C>T | 5'UTR (SNP) | VAF 46/95 reads (48%) | catalogued as COSV100613275; called by muse, mutect2, varscan2
- SPA17 | c.*1219G>A | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- SPATA33 | c.34+189G>A | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- SPEF2 | c.1524+355C>G | Intron (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- SPHK1 | c.11-86C>T | Intron (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SPINK9 | c.87+52G>A | Intron (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- SS18 | c.-29G>A | 5'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
80 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 80 other) are not listed here.
